Somatic mutation profile of tumor specimen TCGA-AA-3488-01A (aliquot TCGA-AA-3488-01A-01D-1408-10) from TCGA case TCGA-AA-3488, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.9 years (21,519 days).
Specimen TCGA-AA-3488-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1a726d4-d244-4d5c-958c-6ebc0b0fa22c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3488-11A (Solid Tissue Normal), aliquot TCGA-AA-3488-11A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57b4fef6-0d8f-4d51-86e8-bceba78658c7

The open-access MAF lists 89 somatic variants for this specimen: 61 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 27, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.2919+1G>A p.X973_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as rs386833575, CS062058, CS1510088; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 92/189 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 96/515 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 71/83 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABLIM2 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211412398; called by muse, mutect2, varscan2
- ADAMTS20 | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745904616; called by muse, mutect2, varscan2
- B4GALNT2 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1212601559; called by muse, mutect2, varscan2
- CDH18 | c.971C>A p.T324N | Missense Mutation (SNP) | VAF 117/137 reads (85%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV56925228; called by muse, mutect2, varscan2
- CENPE | c.5535dup p.V1846Sfs*3 | Frame Shift Ins (INS) | VAF 40/91 reads (44%) | catalogued as rs770905296; called by mutect2, pindel, varscan2
- CENPJ | c.1355C>T p.T452I | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs768672972; called by muse, mutect2, varscan2
- CMYA5 | c.3184C>T p.Q1062* | Nonsense Mutation (SNP) | VAF 55/129 reads (43%) | catalogued as COSV71406180; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>A p.L396H | Missense Mutation (SNP) | VAF 9/277 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2
- CNRIP1 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373164214, COSV99072126; called by muse, mutect2, varscan2
- FANCI | c.2896T>G p.L966V (on ENST00000310775 / NM_001376911.1; = p.L906V on NM_018193.3) | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.482); catalogued as COSV55527674; called by muse, mutect2, varscan2
- FFAR3 | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 116/898 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59909209; called by muse, mutect2, varscan2
- HYDIN | c.12916G>A p.A4306T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs771405246; called by muse, varscan2
- IGF2R | c.914A>G p.N305S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs74483248; called by muse, mutect2, varscan2
- KBTBD7 | c.594C>G p.H198Q | Missense Mutation (SNP) | VAF 167/269 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs761527479; called by muse, mutect2, varscan2
- KIFBP | c.1507G>A p.V503I | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV62831415; called by muse, mutect2, varscan2
- LMNTD1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51445447; called by muse, mutect2, varscan2
- LRFN5 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 76/93 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1224152760, COSV99984449; called by muse, mutect2, varscan2
- MCM3 | c.2056G>A p.D686N (on ENST00000229854 / NM_001366374.2; = p.D676N on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 216/394 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs537125531, COSV57717758; called by muse, mutect2, varscan2
- METTL15 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 37/157 reads (24%) | catalogued as rs1396527830; called by muse, mutect2, varscan2
- NEK1 | c.1562G>A p.R521K | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV71456213, COSV71456668; called by muse, mutect2, varscan2
- NOTCH1 | c.7207del p.Q2403Sfs*19 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as COSV53088547; called by mutect2, varscan2
- NUBP2 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.773); catalogued as rs199651045; called by muse, mutect2, varscan2
- OLAH | c.746T>A p.I249N (on ENST00000378228 / NM_001039702.3; = p.I302N on NM_018324.3) | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62252531; called by muse, mutect2, varscan2
- OPRK1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV55569876; called by muse, mutect2, varscan2
- PON1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs371338407; called by muse, mutect2, varscan2
- SLC45A4 | c.2126C>T p.T709M (on ENST00000517878 / NM_001286646.2; = p.T658M on NM_001080431.2) | Missense Mutation (SNP) | VAF 113/161 reads (70%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as rs762374636, COSV50133823; called by muse, mutect2, varscan2
- TAAR5 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs1349155921; called by muse, mutect2, varscan2
- TFPI2 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745447348; called by muse, mutect2, varscan2
- TTLL5 | c.3376G>T p.V1126L | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV100088940; called by muse, mutect2, varscan2
- UGT1A6 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333719360, COSV59391983; called by muse, mutect2, varscan2
- ZFR2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as rs185400185, COSV53599530, COSV53604876; called by muse, mutect2, varscan2
- ZNF827 | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs759516491, COSV65226629; called by muse, mutect2, varscan2
- ADAMTS5 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- AMBN | c.348G>C p.L116F | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- APAF1 | c.1282C>T p.R428W (on ENST00000551964 / NM_181861.2; = p.R417W on NM_001160.3) | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CD33 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CLSTN3 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPEB2 | c.2209T>A p.L737M | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DSEL | c.3393C>G p.S1131R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- ESPNL | c.1625C>A p.P542H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GGT7 | c.66G>A p.M22I | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); called by muse, varscan2
- GPR42 | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- HEATR1 | c.184T>A p.F62I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- IGHV3-35 | c.195G>T p.E65D | Missense Mutation (SNP) | VAF 100/115 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- NAP1L3 | c.912A>C p.K304N | Missense Mutation (SNP) | VAF 70/78 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NETO1 | c.1175A>G p.H392R | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- OSBPL6 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB7A | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 106/128 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SAGE1 | c.221-1G>T p.X74_splice | Splice Site (SNP) | VAF 240/266 reads (90%) | called by muse, mutect2, varscan2
- SBF2 | c.2590A>T p.R864* | Nonsense Mutation (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- SLMAP | c.1630G>A p.A544T (on ENST00000428312 / NM_001377924.1; = p.A606T on NM_007159.5) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNRPA | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SUCLG2 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC6A | c.5540T>A p.L1847H | Missense Mutation (SNP) | VAF 53/85 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP42 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.415); called by muse, varscan2
- USP42 | c.203T>G p.V68G | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, varscan2
- ZNF2 | c.357dup p.S120Ifs*18 (on ENST00000611147 / NM_001291605.2; = p.S107Ifs*18 on NM_021088.4) | Frame Shift Ins (INS) | VAF 28/140 reads (20%) | called by mutect2, pindel, varscan2
- ADAM23 | c.2148G>A p.P716= | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as rs750323915, COSV52216245, COSV52216476; called by muse, mutect2, varscan2
- ADAMTS13 | c.1392C>T p.G464= | Silent (SNP) | VAF 61/210 reads (29%) | catalogued as rs782239711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALS2CL | c.1128G>A p.P376= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as rs1237625846; called by muse, mutect2, varscan2
- ANK3 | c.5388C>T p.S1796= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as rs369319841, COSV99782105; called by muse, mutect2, varscan2
- CYP11B1 | c.369T>A p.R123= | Silent (SNP) | VAF 18/215 reads (8%) | called by muse, mutect2
- DNAH10 | c.5784G>A p.V1928= (on ENST00000409039; = p.V1867= on NM_207437.3) | Silent (SNP) | VAF 80/279 reads (29%) | catalogued as COSV68997633; called by muse, mutect2, varscan2
- FEZF2 | c.951C>G p.A317= | Silent (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- GAS2L1 | c.210C>T p.T70= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1485331973, COSV53331856; called by muse, mutect2, varscan2
- IRF4 | c.564G>A p.P188= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs773506336, COSV66705244; called by muse, mutect2, varscan2
- LOXL4 | c.1164C>T p.S388= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs138979330; called by muse, mutect2, varscan2
- NFASC | c.3069A>G p.K1023= | Silent (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
- PDZD2 | c.90G>A p.P30= | Silent (SNP) | VAF 98/111 reads (88%) | catalogued as rs754925425, COSV56851708; called by muse, mutect2, varscan2
- PIK3CG | c.234G>A p.A78= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs760275722, COSV63254305; called by muse, mutect2
- PLD4 | c.1359G>A p.T453= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV60918689; called by muse, mutect2, varscan2
- PPP4R3B | c.1806T>C p.D602= (on ENST00000616407 / NM_001122964.3; = p.D517= on NM_020463.4) | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as rs770179049, COSV55404924; called by muse, mutect2, varscan2
- PRDM2 | c.4773A>G p.K1591= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs776719612; called by muse, mutect2, varscan2
- PXDNL | c.4110G>A p.A1370= | Silent (SNP) | VAF 97/210 reads (46%) | catalogued as rs902065078, COSV62487994; called by muse, mutect2, varscan2
- ROBO1 | c.4182C>T p.D1394= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs531340562, COSV71394682; called by muse, mutect2, varscan2
- ROR2 | c.1776C>T p.F592= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs747072020, COSV65217690; ClinVar: likely benign; called by muse, mutect2, varscan2
- SETX | c.3435G>A p.R1145= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as COSV99809840; called by muse, mutect2, varscan2
- SH2B3 | c.1383C>T p.Y461= | Silent (SNP) | VAF 39/67 reads (58%) | catalogued as rs780551907, COSV57984572; called by muse, mutect2, varscan2
- SLC9A4 | c.930C>T p.S310= | Silent (SNP) | VAF 61/205 reads (30%) | called by muse, mutect2, varscan2
- SPON1 | c.489C>T p.I163= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs782789975, COSV59959608; called by muse, mutect2, varscan2
- TEPSIN | c.885C>T p.C295= | Silent (SNP) | VAF 50/79 reads (63%) | called by muse, mutect2, varscan2
- TLN2 | c.5901G>A p.S1967= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs758944577; called by muse, mutect2, varscan2
- USP42 | c.204A>C p.V68= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs942118507; called by muse, varscan2
- ZNF22 | c.72C>T p.R24= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1597A>C | RNA (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
